Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7331, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7331-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date: [REDACTED]

PART 1:

PROSTATE AND BILATERAL SEMINAL VESICLES, PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- B. TUMOR INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.3 CM.
- C. THE TUMOR INVOLVES LESS THAN 5% OF THE TOTAL PROSTATE VOLUME.
- D. THE TUMOR IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES AND VAS DEFERENS ARE FREE OF TUMOR.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. BENIGN PROSTATIC GLANDS ARE PRESENT AT THE INKED SURGICAL MARGIN.
- H. FOCAL PERINEURAL INVASION IS IDENTIFIED.
- I. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. TNM PATHOLOGIC STAGE = pT2c N0 MX.
- L. TNM HISTOLOGIC GRADE = G1.
- M. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC MODERATELY ACTIVE PROSTATITIS ARE NOTED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN SEVEN (0/7) LYMPH NODES EXAMINED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 7
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	40%
WEIGHT OF PROSTATE:	41.6gm
TUMOR SIZE:	Maximum dimension: 1.3 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	< 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	7
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 0eccd8a8-93b0-4599-8953-8964fbb0584b (TCGA-EJ-7331.84790D75-BBEF-49B0-9486-94E049C13DDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).